Somatic mutation profile of tumor specimen 0DVKDY from CCDI case PBCMTW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.6 years (4,952 days).
Specimen 0DVKDY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 724c0431-0d20-46f0-b675-971888146170.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVKEG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e3746e5-b5ac-460e-9757-4299bea27813

The open-access MAF lists 26 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Intron 5, 5'UTR 3, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 224/551 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 531/681 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS8 | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 210/302 reads (70%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs771285887; called by muse, mutect2, varscan2
- DAGLA | c.1163A>G p.H388R | Missense Mutation (SNP) | VAF 90/317 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs769565314; called by muse, mutect2, varscan2
- NFYA | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 103/463 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs756585756; called by muse, mutect2, varscan2
- BRSK2 | c.2093A>T p.H698L | Missense Mutation (SNP) | VAF 181/467 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CORIN | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 101/813 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NWD2 | c.4876C>T p.Q1626* | Nonsense Mutation (SNP) | VAF 213/925 reads (23%) | called by muse, mutect2, varscan2
- PABPC4L | c.1016T>C p.F339S | Missense Mutation (SNP) | VAF 61/544 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- RYR2 | c.157T>A p.S53T | Missense Mutation (SNP) | VAF 54/766 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2
- SORCS2 | c.179C>G p.P60R | Missense Mutation (SNP) | VAF 73/632 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- VPS72 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 116/601 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- FBXO21 | c.1260G>A p.P420= | Silent (SNP) | VAF 115/512 reads (22%) | catalogued as rs763878747; called by muse, mutect2, varscan2
- FLNB | c.6855C>T p.D2285= | Silent (SNP) | VAF 195/564 reads (35%) | catalogued as rs770627079, COSV55892285; called by muse, mutect2, varscan2
- KCNV2 | c.78C>T p.H26= | Silent (SNP) | VAF 98/390 reads (25%) | catalogued as rs1358641807; called by muse, mutect2, varscan2
- RANBP2 | c.7107T>C p.R2369= | Silent (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- SKIDA1 | c.825C>T p.R275= | Silent (SNP) | VAF 119/277 reads (43%) | catalogued as rs1043756876; called by muse, mutect2, varscan2
- BACE2 | c.619-10C>A | Intron (SNP) | VAF 88/423 reads (21%) | called by muse, mutect2, varscan2
- DIP2C | c.85+39481G>T | Intron (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- FDFT1 | c.100-205G>T | Intron (SNP) | VAF 20/592 reads (3%) | catalogued as rs1430364039; called by muse, mutect2
- MED6 | chr14:70600681 A>G | 5'Flank (SNP) | VAF 30/217 reads (14%) | called by muse, mutect2, varscan2
- MORC1 | c.-56C>T | 5'UTR (SNP) | VAF 82/192 reads (43%) | called by muse, mutect2, varscan2
- NES | c.-83T>A | 5'UTR (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- PPP2R2C | c.71-772G>A | Intron (SNP) | VAF 28/320 reads (9%) | called by muse, mutect2
- TVP23A | c.-37C>T | 5'UTR (SNP) | VAF 55/421 reads (13%) | called by muse, mutect2, varscan2
- ZCCHC8 | c.605+54T>G | Intron (SNP) | VAF 133/251 reads (53%) | called by muse, mutect2, varscan2
